Somatic mutation profile of tumor specimen MMRF_1460_1_BM_CD138pos (aliquot MMRF_1460_1_BM_CD138pos_T1_KAS5U_L01603) from MMRF case MMRF_1460, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 85.6 years (31,277 days).
Specimen MMRF_1460_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d07f3157-4168-459d-b93e-782bc7013348.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1460_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1460_1_PB_Whole_C2_KAS5U_L01612; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ed6243b-f893-42b6-aa39-b72a4d2c5c47

The open-access MAF lists 97 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 20, Intron 14, Silent 8, 5'UTR 5, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1C | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757354662; called by muse, mutect2, varscan2
- ATP1B1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs772932534; called by muse, mutect2, varscan2
- BAG6 | c.1760G>C p.G587A (on ENST00000676571; = p.G540A on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764944108; called by muse, mutect2, varscan2
- BCLAF1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.306); catalogued as rs1466174795; called by muse, mutect2
- CPA4 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs781426403; called by muse, mutect2, varscan2
- CSMD3 | c.10763C>T p.A3588V (on ENST00000297405 / NM_001363185.1; = p.A3419V on NM_052900.3) | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs1400237894, COSV99847759; called by muse, mutect2, varscan2
- DLGAP2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770007555, COSV70096348; called by muse, mutect2, varscan2
- KIAA1109 | c.10519A>G p.M3507V | Missense Mutation (SNP) | VAF 142/434 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs773245647, COSV52688683; called by muse, mutect2, varscan2
- KREMEN2 | c.1258T>C p.Y420H (on ENST00000303746 / NM_172229.3; = p.G393= on NM_024507.4) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750788121; called by muse, mutect2, varscan2
- NPAP1 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 86/407 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.151); catalogued as rs376537526; called by muse, mutect2, varscan2
- PHLDB1 | c.3550C>T p.R1184W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs782462086, COSV61877334; called by muse, mutect2, varscan2
- PRUNE2 | c.5830G>A p.A1944T | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65043479; called by muse, mutect2, varscan2
- PTPRJ | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs377700940; called by muse, mutect2
- PTPRS | c.4027C>T p.R1343C | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753143589, COSV53635575; called by muse, mutect2, varscan2
- RALYL | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV72818946; called by muse, mutect2, varscan2
- SLC17A2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as rs767504915, COSV99613903; called by muse, mutect2, varscan2
- SOWAHB | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs1308144207; called by muse, mutect2, varscan2
- SPATA16 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1438359903; called by muse, mutect2, varscan2
- TENM1 | c.6584G>A p.R2195Q | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1336156639; called by muse, mutect2, varscan2
- TRABD2A | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755718967; called by muse, mutect2, varscan2
- XRN2 | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101018505; called by muse, mutect2, varscan2
- ACTL7B | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ADARB2 | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADGRG4 | c.8290A>G p.T2764A | Missense Mutation (SNP) | VAF 95/97 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- APOE | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- BDP1 | c.5541dup p.R1848Tfs*5 | Frame Shift Ins (INS) | VAF 92/314 reads (29%) | called by mutect2, pindel, varscan2
- COL20A1 | c.1562T>C p.V521A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FOCAD | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 194/632 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FYB1 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- HIP1 | c.1819A>T p.S607C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGHV2-70D | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- KIF2B | c.1325A>T p.K442M | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAGI2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- METTL3 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- METTL7A | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NFKBIA | c.239T>A p.L80* | Nonsense Mutation (SNP) | VAF 63/78 reads (81%) | called by muse, mutect2, varscan2
- OR2G6 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RBM20 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A13 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SYCP2 | c.1206T>G p.I402M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TNRC6C | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBE2D1 | c.399-3C>G | Splice Region (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- UNC13B | c.4181A>T p.Y1394F | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- USP9X | c.7487del p.D2496Vfs*47 | Frame Shift Del (DEL) | VAF 111/159 reads (70%) | called by mutect2, pindel, varscan2
- VCAN | c.7566C>A p.D2522E | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- VEZF1 | c.182A>C p.D61A | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF492 | c.1547A>C p.N516T | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF648 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ACTL7B | c.924A>T p.A308= | Silent (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- FBXL4 | c.810C>A p.V270= | Silent (SNP) | VAF 163/366 reads (45%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.207T>C p.D69= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs376461282; called by muse, mutect2, varscan2
- LRBA | c.2967T>C p.G989= | Silent (SNP) | VAF 41/157 reads (26%) | called by muse, mutect2, varscan2
- PIF1 | c.429G>A p.R143= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as rs755045906; called by muse, mutect2, varscan2
- SLC34A1 | c.1659C>T p.A553= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as rs1038553627; called by muse, mutect2, varscan2
- TRIM10 | c.522C>A p.L174= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.606C>T p.G202= | Silent (SNP) | VAF 43/128 reads (34%) | called by muse, mutect2, varscan2
- AFDN | c.4947+550_4947+551del | Intron (DEL) | VAF 7/81 reads (9%) | catalogued as rs944455872; called by mutect2, pindel
- ATP6V0A2 | c.*50T>C | 3'UTR (SNP) | VAF 141/322 reads (44%) | called by muse, mutect2, varscan2
- BCLAF1P2 | n.602A>G | RNA (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- C6orf120 | c.*1095A>G | 3'UTR (SNP) | VAF 33/42 reads (79%) | called by muse, mutect2, varscan2
- CDH4 | c.170-25680G>A | Intron (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2
- CDK5 | c.-1G>C | 5'UTR (SNP) | VAF 88/197 reads (45%) | catalogued as COSV52529125; called by muse, mutect2, varscan2
- CLIP4 | c.*1694_*1695del | 3'UTR (DEL) | VAF 58/171 reads (34%) | called by mutect2, pindel, varscan2
- CNBD1 | c.-25A>T | 5'UTR (SNP) | VAF 148/324 reads (46%) | called by muse, mutect2, varscan2
- COBLL1 | c.*2597C>G | 3'UTR (SNP) | VAF 44/160 reads (28%) | catalogued as rs951543443; called by muse, mutect2, varscan2
- CREG2 | c.*1226A>G | 3'UTR (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- FBXL17 | c.*552C>A | 3'UTR (SNP) | VAF 61/170 reads (36%) | called by muse, mutect2, varscan2
- FEM1B | c.*951G>A | 3'UTR (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- FMN1 | c.2044-1889C>T | Intron (SNP) | VAF 25/197 reads (13%) | catalogued as COSV57917304; called by muse, mutect2, varscan2
- HM13 | c.*305A>C | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*7245C>T | 3'UTR (SNP) | VAF 20/58 reads (34%) | catalogued as rs994572817; called by muse, mutect2
- MAP3K21 | c.1675+581A>G | Intron (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- MTUS2 | c.*623C>T | 3'UTR (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*2205T>C | 3'UTR (SNP) | VAF 45/131 reads (34%) | catalogued as rs755783140; called by muse, mutect2, varscan2
- PAXBP1 | c.2334+337C>G | Intron (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*2584T>G | 3'UTR (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+1871del | Intron (DEL) | VAF 88/140 reads (63%) | catalogued as rs200682273; called by mutect2, varscan2
- PPFIA4 | c.-62-84G>A | Intron (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- PURB | c.*4419C>A | 3'UTR (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- RABL6 | c.810-256C>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- RBM27 | c.1894-112T>C | Intron (SNP) | VAF 3/11 reads (27%) | catalogued as rs1441921118; called by muse, mutect2
- RETREG1 | c.459-25178G>T | Intron (SNP) | VAF 116/445 reads (26%) | called by muse, mutect2, varscan2
- RMDN3 | c.-477G>A | 5'UTR (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- SEC14L2 | c.*804C>G | 3'UTR (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- SEPTIN6 | c.1281-1202C>A | Intron (SNP) | VAF 130/139 reads (94%) | catalogued as COSV100595408; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*2853G>A | 3'UTR (SNP) | VAF 64/97 reads (66%) | called by muse, mutect2, varscan2
- STK10 | c.*2001G>A | 3'UTR (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- SV2B | c.*2954A>G | 3'UTR (SNP) | VAF 55/156 reads (35%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1203+52G>C | Intron (SNP) | VAF 34/40 reads (85%) | called by muse, mutect2, varscan2
- TEKT4 | c.498+622C>T | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as rs113502626; called by muse, varscan2
- TNPO1 | c.*936C>T | 3'UTR (SNP) | VAF 68/239 reads (28%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2912+33282A>G | Intron (SNP) | VAF 46/54 reads (85%) | called by muse, mutect2, varscan2
- UGT3A1 | c.*2006T>C | 3'UTR (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- USP19 | c.-1G>T | 5'UTR (SNP) | VAF 72/169 reads (43%) | called by muse, mutect2, varscan2
- UTP15 | c.-72A>C | 5'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- VPS37B | c.*1322T>C | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- ZNF404 | chr19:43883991 G>T | 5'Flank (SNP) | VAF 48/245 reads (20%) | called by muse, mutect2, varscan2
